Gene-level copy-number profile of specimen HCM-SANG-0269-C18-85A-01D-A80T-32 from HCMI case HCM-SANG-0269-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; Tumor grade: G2.
Specimen HCM-SANG-0269-C18-85A-01D-A80T-32: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file da8c5314-5390-4c6a-b5be-3f1fc1e51bb2.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0269-C18-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,714 have no estimate.
https://portal.gdc.cancer.gov/files/6d595b88-5095-4910-b8fd-eff19ac1b6fc

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 512; copy number 1: 2,092; copy number 2: 10,511; copy number 3: 28,969; copy number 4: 12,710; copy number 5: 2,523; copy number 6: 1,303; copy number 7: 274; copy number 8: 13; copy number 9: 1; copy number 15: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 289 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:46,734,827–46,993,581, 2 genes, copy number 7: COX7B2, GABRA4.
- chr6:42,050,513–44,553,281, 96 genes, copy number 7 (broad region; genes not listed).
- chr6:46,652,915–47,309,905, 11 genes, copy number 7: SLC25A27, AL591242.1, TDRD6, PLA2G7, ANKRD66, AL161618.1, MEP1A, ADGRF5, ADGRF5-AS1, ADGRF1, TNFRSF21.
- chr6:57,314,805–57,646,850, 3 genes, copy number 7: PRIM2, MIR548U, FO680682.1.
- chr6:75,084,326–75,919,537, 22 genes, copy number 7: COL12A1, COX7A2, TMEM30A, TMEM30A-DT, FILIP1, HMGB1P39, AL445465.1, U3, MIR4463, AL445465.2, UBE2V1P15, RNU1-34P, RPL26P20, H3P27, RNU6-1338P, SENP6, AL356057.1, RNU6-1016P, RN7SKP163, MYO6, RNU6-155P, RNA5SP209.
- chr8:40,104,169–40,127,468, 2 genes, copy number 9–15: AC087518.1, LINC02866.
- chr8:41,509,593–41,578,421, 1 gene, copy number 7 (within-gene range 5–7): AC009630.1.
- chr8:41,540,381–41,625,001, 4 genes, copy number 7 (within-gene range 5–7): AC009630.2, AC009630.4, GPAT4, AC009630.3.
- chr8:41,653,220–41,896,762, 1 gene, copy number 7 (within-gene range 6–7): ANK1.
- chr8:41,803,349–42,555,195, 21 genes, copy number 7: Y_RNA, AC027702.1, RN7SL149P, KAT6A, AC090571.1, AC103724.1, AC103724.2, AC103724.4, AC103724.3, AP3M2, PLAT, AC083973.1, IKBKB, POLB, RPL5P23, DKK4, VDAC3, SLC20A2, AC093367.1, AC090739.1, SMIM19.
- chr8:81,439,436–81,521,818, 1 gene, copy number 7 (within-gene range 6–7): AC018616.1.
- chr8:81,458,253–81,698,694, 12 genes, copy number 7 (within-gene range 6–7): FABP9, FABP4, AC023644.1, FTH1P11, FABP12, IMPA1P1, NIPA2P4, RPS26P34, SLC10A5P1, IMPA1, SLC10A5, AC132219.2.
- chr8:94,127,162–95,116,455, 32 genes, copy number 7 (within-gene range 5–7): CDH17, AP003478.1, GEM, RPS4XP10, RAD54B, FSBP, VIRMA, AC023632.5, AC023632.2, AC023632.1, AC023632.3, AC023632.4, AC108860.2, ESRP1, Metazoa_SRP, AC108860.1, AP005660.1, Y_RNA, DPY19L4, AP003692.1, INTS8, CCNE2, AC087752.4, AC087752.1, NDUFAF6, TP53INP1, AC087752.3, AC087752.2, AC068189.2, RNU6-1209P, MIR3150BHG, AC068189.1.
- chr20:3,659,248–5,611,006, 60 genes, copy number 7–8: GFRA4, ADAM33, SIGLEC1, HSPA12B, C20orf27, SPEF1, CENPB, CDC25B, LINC01730, AL109804.1, AP5S1, MAVS, PANK2-AS1, PANK2, MIR103A2, MIR103B2, AL031670.1, RNF24, FTLP3, RPL21P2, AL356414.1, SMOX, LINC01433, ADRA1D, AL139350.1, AL121781.1, AL121916.1, RPS4XP2, PRNP, PRND, PRNT, IDI1P3, AL133396.1, RASSF2, SLC23A2, AL389886.1, AL121890.1, AL121890.3, AL121890.2, AL121890.5, AL121890.4, TMEM230, RNA5SP474, Y_RNA, PCNA, AL121924.1, CDS2, UBE2D3P1, PROKR2, AL121757.2, RNA5-8SP7, AL121757.3, LINC00658, AL121757.1, LINC00654, LINC01729, RPS18P1, AL109935.1, GPCPD1, EIF4EP1.
- chr20:9,068,763–10,434,222, 21 genes, copy number 7: PLCB4, LAMP5-AS1, LAMP5, PAK5, AL353612.2, AL353612.1, AL034427.1, PARAL1, ANKEF1, SNAP25-AS1, Metazoa_SRP, AL354824.1, AL354824.2, SNAP25, AL023913.1, HIGD1AP15, RPL23AP6, SDAD1P2, MKKS, AL034430.1, AL034430.2.

Autosomal genes at a single copy (total copy number 1): 2,092. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
